Surgical pathology report (de-identified scan), TCGA case TCGA-D1-A16Q, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Mayo Clinic, specimen TCGA-D1-A16Q-01A (Primary Tumor).

[page 1 of 6]
100-0-1
Adenocarcinoma, Endometrioid, NOS

8380/3 12/19/10

Site Code: Endometrium
C54.1

Surgical Pathology

SLIDE DISPOSITION:

DIAGNOSIS:

A. Uterus, bilateral ovaries and fallopian tubes;
hysterectomy and
bilateral salpingo-oophorectomy: FIGO grade 2 (of 3)
endometrial
adenocarcinoma, endometrioid type, is identified forming
an 8.2 x
4.5 x 1.4 cm mass, involving the entire endometrial
cavity. The
tumor superficially invades the myometrium but deeply
invades 1.4 cm
into the endocervix (total endocervical thickness 1.8 cm).
Lymphovascular space invasion is identified. There are
multiple (1
cellular intramural, 5.0 x 4.3 x 3.8 cm; 5 intramural,
ranging in
size from 0.4 cm to 4.0 cm in greatest dimension; 9
subserosal,
ranging in size from 0.6 cm to 3.2 cm in greatest
dimension; 2
submucosal, 0.3 cm and 1.3 cm in greatest dimension)
leiomyomata in
the myometrium. The vaginal cuff margin and right and
left
parametrium are negative for tumor. The bilateral ovaries
and
fallopian tubes are not involved.

B. Lymph nodes, left pelvic, lymphadenectomy: Multiple
(37) left
pelvic lymph nodes are negative for tumor.

C. Lymph nodes, right pelvic, lymphadenectomy: Multiple
(37) right
pelvic lymph nodes are negative for tumor.

D. Lymph nodes, right para-aortic above the inferior
mesenteric
artery, lymphadenectomy: Multiple (16) right para-aortic
lymph

[page 2 of 6]
nodes above the inferior mesenteric artery are negative for tumor.

E. Lymph nodes, right para-aortic below the inferior mesenteric artery, lymphadenectomy: Multiple (3) right para-aortic lymph nodes below the inferior mesenteric artery are negative for tumor.

F. Gonadal vessel, right, excision: The right gonadal vessel is negative for tumor.

G. Gonadal vessel, left, excision: The left gonadal vessel is negative for tumor.

H. Lymph nodes, left para-aortic above the inferior mesenteric artery, lymphadenectomy: Multiple (5) left para-aortic lymph nodes above the inferior mesenteric artery are negative for tumor.

I. Lymph nodes, left para-aortic below the inferior mesenteric artery, lymphadenectomy: Multiple (6) left para-aortic lymph nodes below the inferior mesenteric artery are negative for tumor.

With available surgical materials, [AJCC pT2N0] (7th edition, 2010).

PRELIMINARY FROZEN SECTION CONSULTATION:

A. Uterus, bilateral ovaries and fallopian tubes; hysterectomy and bilateral salpingo-oophorectomy: Endometrial adenocarcinoma. The tumor superficially invades the myometrium but deeply invades the endocervix. Multiple leiomyomata The vaginal cuff margin and right

[page 3 of 6]
and left parametrium are negative for tumor. The bilateral ovaries and fallopian tubes are not involved. HOLD to confirm.

B. Lymph nodes, left pelvic, lymphadenectomy: Multiple lymph nodes are negative for tumor. HOLD to confirm.

C. Lymph nodes, right pelvic, lymphadenectomy: Multiple lymph nodes are negative for tumor. HOLD to confirm.

D. Lymph nodes, right para-aortic above the inferior mesenteric artery, lymphadenectomy: Multiple lymph nodes are negative for tumor. HOLD to confirm.

E. Lymph nodes, right para-aortic below the inferior mesenteric artery, lymphadenectomy: Multiple lymph nodes are negative for tumor. HOLD to confirm.

F. Gonadal vessel, right, excision: The right gonadal vessel is negative for tumor.

G. Gonadal vessel, left, excision: The left gonadal vessel is negative for tumor.

H. Lymph nodes, left para-aortic above the inferior mesenteric artery, lymphadenectomy: Multiple lymph nodes are negative for tumor. HOLD to confirm.

I. Lymph nodes, left para-aortic below the inferior mesenteric artery, lymphadenectomy: Multiple lymph nodes are negative for tumor. HOLD to confirm.

GROSS DESCRIPTION:

[page 4 of 6]
A. Received fresh labeled "uterus, bilateral fallopian tubes and ovaries" is a 390.0 gram uterus with attached bilateral fallopian tubes and ovaries. The uterine serosa is smooth. There is an 8.2 x 4.5 x 1.4 cm polypoid mass involving the entire endometrial cavity, lower uterine segment, and endocervix with the deepest invasion in the endocervix (1.4 cm invasion into a 1.8 cm endocervical thickness). There are multiple (1 cellular intramural, 5.0 x 4.3 x 3.8 cm; 5 intramural, ranging in size from 0.4 cm to 4.0 cm in greatest dimension; 9 subserosal, ranging in size from 0.6 cm to 3.2 cm in greatest dimension; 2 submucosal, 0.3 cm and 1.3 cm in greatest dimension) leiomyomata in the myometrium. There is a 3.7 x 2.0 x 1.9 cm right ovary with a smooth outer surface and a solid cut surface with an 11.2 x 0.6 cm right fallopian tube, which is unremarkable. There is a 2.7 x 2.3 x 1.6 cm left ovary with a smooth outer surface and a solid cut surface with a 9.7 x 0.5 cm left fallopian tube, which is unremarkable. Representative sections are submitted.

B. Received fresh labeled "left pelvic lymph nodes" is a 10.3 x 7.4 x 2.5 cm aggregate of adipose and lymphatic tissue. Multiple (40) lymph nodes are identified. All lymph nodes submitted.

C. Received fresh labeled "right pelvic lymph nodes" is a 9.4 x 6.3 x 2.7 cm aggregate of adipose and lymphatic tissue and lymph nodes. Multiple (31) lymph nodes are identified. All lymph nodes submitted.

[page 5 of 6]
D. Received fresh labeled "right para-aortic lymph nodes above IMA"
is a 9.7 x 3.8 x 1.4 cm aggregate of adipose and lymphatic tissue.
All lymph nodes submitted.

E. Received fresh labeled "right para-aortic lymph nodes below IMA"
is a 4.2 x 2.1 x 1.0 cm aggregate of adipose and lymphatic tissue.
All lymph nodes submitted.

F. Received fresh labeled "right gonadal vessels" is a 7.5 cm in
length by 0.3 cm in diameter portion of unremarkable blood vessel.
A representative section is submitted.

G. Received fresh labeled "left gonadal vessels" is a 1.8 cm in
length by 0.3 cm in diameter portion of blood vessel. A representative section is submitted.

H. Received fresh labeled "left para-aortic lymph nodes above IMA"
is a 4.9 x 3.1 x 2.0 cm aggregate of adipose and lymphatic tissue.
All lymph nodes submitted.

I. Received fresh labeled "left para-aortic lymph nodes below IMA"
is a 6.2 x 2.8 x 1.2 cm aggregate of adipose and lymphatic tissue.
All lymph nodes submitted.

BLOCK SUMMARY:

Part A: Uterus, bilateral fallopian tubes and ovaries

- 1 Vaginal cuff margin 6:00
- 2 Right parametrium
- 3 Left parametrium
- 4 Right fallopian tube
- 5 Right ovary
- 6 Left fallopian tube
- 7 Left ovary
- 8 Myometrium(leiomyoma)
- 9 Cervix 6:00
- 10 Endometrium-1

[page 6 of 6]
3 Lt PA above IMA LN 1(H3)

Part I: Left Para-aortic Below Inferior Mesenteric Artery
Lymph
Nodes

- 1 Lt PA below IMA LN 3(I1)
- 2 Lt PA below IMA LN 3(I2)
- 3 Lt PA below IMA LN 1of2(I3)
- 4 Lt PA below IMA LN 2of2(I3)
- 5 Lt PA below IMA LN 1(I4)
- 6 Lt PA below IMA LN 1of2(I5)
- 7 Lt PA below IMA LN 2of2(I5)

Source: NCI Genomic Data Commons file bf3c44e2-61a8-480e-b014-77ccf72331a4 (TCGA-D1-A16Q.60635568-D27E-4C72-BFF2-238CF2992925.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).